CCDI case PBCKXI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4506a1a1-0dab-4756-a1bd-6c7f8dcd5b7f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,553 days).

Biospecimens (3 samples)
- Sample 0DUFDA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUFE0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUFE9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
